Somatic mutation profile of tumor specimen MMRF_2336_1_BM_CD138pos (aliquot MMRF_2336_1_BM_CD138pos_T1_KHS5U_L11034) from MMRF case MMRF_2336, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.2 years (23,093 days).
Specimen MMRF_2336_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f19568c-ec29-4ace-a558-7fb4136948d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2336_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2336_1_PB_WBC_C2_KHS5U_L11033; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c7423e5-92c0-4761-a082-75d4c27b5148

The open-access MAF lists 118 somatic variants for this specimen: 55 protein-altering or splice-affecting, 14 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 30, Silent 14, Intron 12, Nonsense Mutation 4, 5'UTR 3, 3'Flank 3, Frame Shift Del 2, Frame Shift Ins 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 32/512 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ARFGEF1 | c.2648C>G p.S883* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99145043; called by muse, mutect2, varscan2
- ASAP3 | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs750016708, COSV100369213; called by muse, mutect2, varscan2
- CENPU | c.710T>A p.I237N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99859801; called by muse, mutect2
- COL9A3 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 46/213 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs759094051, COSV58985192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORIN | c.2132A>G p.H711R | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.109); catalogued as COSV56689638; called by muse, mutect2, varscan2
- FAT3 | c.8773G>A p.A2925T | Missense Mutation (SNP) | VAF 53/283 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.108); catalogued as rs745373906, COSV53085882; called by muse, mutect2, varscan2
- FSD1 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298919110; called by muse, mutect2, varscan2
- GRIK5 | c.2134G>A p.V712I | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs543302397, COSV53474625; called by muse, mutect2, varscan2
- HECW1 | c.1974C>A p.S658R | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.689); catalogued as COSV67821457; called by muse, mutect2, varscan2
- KBTBD12 | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 72/349 reads (21%) | catalogued as rs775293018; called by muse, mutect2, varscan2
- LGALS4 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs376691080; called by muse, mutect2
- NEK10 | c.2108G>A p.S703N | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0.019); catalogued as rs764275142; called by muse, varscan2
- NLRP7 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.352); catalogued as rs774667662; called by muse, varscan2
- NTRK3 | c.2120C>T p.T707M | Missense Mutation (SNP) | VAF 168/404 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); catalogued as rs776296223, COSV62296617; called by muse, mutect2, varscan2
- OR9G4 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs139616824, COSV57248756; called by muse, varscan2
- PGM3 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 80/347 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.755); catalogued as COSV99392245; called by muse, mutect2, varscan2
- PIK3R6 | c.192G>A p.A64= | Splice Region (SNP) | VAF 38/175 reads (22%) | catalogued as rs149242502, COSV61006412; called by muse, mutect2, varscan2
- PKDREJ | c.3784G>A p.D1262N | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs763497870, COSV53549199; called by muse, mutect2
- PSG1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.623); catalogued as rs150536125; called by muse, mutect2, varscan2
- PTCHD3 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs1376155004, COSV71256787; called by muse, mutect2, varscan2
- RASEF | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV61551035; called by muse, mutect2, varscan2
- ST7 | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs201501046; called by muse, mutect2
- TET2 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 65/158 reads (41%) | catalogued as rs1340173182, COSV54395421; called by muse, mutect2, varscan2
- ZFHX4 | c.8855G>A p.R2952Q | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51452712; called by muse, mutect2, varscan2
- CATSPERB | c.691A>C p.I231L | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CD320 | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CHD7 | c.5417A>G p.Y1806C | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CLASP1 | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- CSMD3 | c.7709G>A p.S2570N (on ENST00000297405 / NM_001363185.1; = p.S2466N on NM_052900.3) | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CUL4B | c.2120T>C p.I707T | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- FAM171B | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM171B | c.347T>C p.V116A | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GRHPR | c.916T>G p.S306A | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.011); called by muse, varscan2
- GRIN2B | c.2498T>C p.L833P | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GRN | c.1270G>C p.A424P | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HECTD4 | c.4699G>A p.A1567T | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); called by muse, mutect2
- IDO1 | c.617G>T p.C206F | Missense Mutation (SNP) | VAF 9/237 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2
- KDM5B | c.4613A>C p.K1538T | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- LGI3 | c.715T>C p.F239L | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- MICALL1 | c.2407G>C p.D803H | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH11 | c.4154G>A p.S1385N | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NEK10 | c.2093C>G p.P698R | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- PCDH7 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 84/249 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PPFIA2 | c.3127G>T p.E1043* | Nonsense Mutation (SNP) | VAF 7/183 reads (4%) | called by muse, mutect2
- PPP4R1 | c.161A>C p.Y54S (on ENST00000400556 / NM_001042388.3; = p.Y37S on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PTPN4 | c.2055_2056del p.Y685* | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- SCN3A | c.1775A>T p.D592V | Missense Mutation (SNP) | VAF 69/245 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- SLC35D1 | c.322A>G p.K108E | Missense Mutation (SNP) | VAF 75/154 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- SPAG17 | c.459C>A p.D153E | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TENT5C | c.208dup p.R70Pfs*40 | Frame Shift Ins (INS) | VAF 26/111 reads (23%) | called by mutect2, pindel, varscan2
- UBR4 | c.8114T>C p.L2705P | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- XPO6 | c.1921G>C p.E641Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZFYVE28 | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- ZNF135 | c.871del p.T291Lfs*79 (on ENST00000313434 / NM_001289401.2; = p.T303Lfs*79 on NM_003436.4) | Frame Shift Del (DEL) | VAF 63/169 reads (37%) | called by mutect2, pindel, varscan2
- ADGB | c.783G>A p.G261= | Silent (SNP) | VAF 46/240 reads (19%) | called by muse, mutect2, varscan2
- ANKRD33B | c.1431C>T p.R477= | Silent (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- ARHGAP4 | c.1161G>A p.L387= | Silent (SNP) | VAF 4/57 reads (7%) | catalogued as rs782547689; called by muse, mutect2
- C8A | c.1542C>T p.S514= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs755002323; called by muse, mutect2, varscan2
- CCDC168 | c.14721C>G p.L4907= | Silent (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- CDH6 | c.1806G>A p.A602= | Silent (SNP) | VAF 39/207 reads (19%) | catalogued as rs762159696, COSV54064012; called by muse, mutect2, varscan2
- CRYAB | c.447G>A p.R149= | Silent (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- EVA1A | c.309C>T p.F103= | Silent (SNP) | VAF 60/115 reads (52%) | catalogued as rs750871767, COSV99285620; called by muse, mutect2, varscan2
- FLNB | c.3765T>G p.S1255= | Silent (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- HS3ST3B1 | c.636G>A p.A212= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as rs760721398; called by muse, mutect2, varscan2
- IGLL5 | c.79C>T p.L27= | Silent (SNP) | VAF 38/63 reads (60%) | catalogued as rs777349722, COSV73249535, COSV73250343, COSV73250409; called by muse, mutect2, varscan2
- KLK14 | c.492C>T p.C164= | Silent (SNP) | VAF 36/206 reads (17%) | catalogued as rs377230129, COSV99335777; called by muse, mutect2, varscan2
- LILRB2 | c.1416G>A p.L472= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV100079589; called by muse, varscan2
- RBM33 | c.1029G>T p.P343= | Silent (SNP) | VAF 23/144 reads (16%) | called by muse, mutect2, varscan2
- ABCA10 | c.*765T>A | 3'UTR (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- ADCY1 | c.*7434del | 3'UTR (DEL) | VAF 16/80 reads (20%) | called by mutect2, pindel, varscan2
- AKAP13 | c.5533-102G>C | Intron (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- ANKS1B | c.3672+6116A>C | Intron (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- ATP5PB | c.*270del | 3'UTR (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel, varscan2
- BCLAF3 | chrX:19916234 C>A | 3'Flank (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- CCER1 | c.-207C>T | 5'UTR (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- CCNT2 | c.*484_*487del | 3'UTR (DEL) | VAF 20/44 reads (45%) | catalogued as rs1033687945; called by pindel, varscan2
- CNKSR3 | c.-515G>C | 5'UTR (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- CNN1 | c.648+36_649-33del | Intron (DEL) | VAF 25/168 reads (15%) | called by mutect2, pindel, varscan2
- COA5 | c.*338C>G | 3'UTR (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- CPEB4 | c.*4526T>C | 3'UTR (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- CSNK1G1 | c.*3914T>C | 3'UTR (SNP) | VAF 16/75 reads (21%) | catalogued as rs1157838518; called by muse, mutect2, varscan2
- CTDSPL2 | c.*2210C>T | 3'UTR (SNP) | VAF 3/42 reads (7%) | catalogued as rs1304406158; called by muse, mutect2
- CTNNA2 | c.1057-230747C>T | Intron (SNP) | VAF 62/263 reads (24%) | catalogued as rs189678763; called by muse, mutect2, varscan2
- CXCL14 | c.-46G>T | 5'UTR (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- CYP1B1 | c.*998C>G | 3'UTR (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- DBNL | c.*5483G>C | 3'UTR (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- DDX27 | c.1781-91C>T | Intron (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- ERLIN2 | c.-15-40C>T | Intron (SNP) | VAF 51/152 reads (34%) | called by muse, mutect2, varscan2
- FER | c.*7203G>A | 3'UTR (SNP) | VAF 4/70 reads (6%) | catalogued as rs1470933716; called by muse, mutect2
- FGF18 | c.*559C>T | 3'UTR (SNP) | VAF 46/298 reads (15%) | catalogued as rs539224505; called by muse, mutect2, varscan2
- GPR88 | c.*1215G>T | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- IARS1 | c.*224G>A | 3'UTR (SNP) | VAF 29/117 reads (25%) | called by muse, mutect2, varscan2
- IL1RL1 | c.970+756G>T | Intron (SNP) | VAF 4/39 reads (10%) | catalogued as rs1470699948; called by mutect2, varscan2
- LUC7L3 | chr17:50753453 C>T | 3'Flank (SNP) | VAF 19/63 reads (30%) | catalogued as rs1193792964; called by muse, mutect2, varscan2
- MCMDC2 | c.*732G>A | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- MDM4 | c.*175T>A | 3'UTR (SNP) | VAF 22/88 reads (25%) | catalogued as rs1298512094; called by muse, mutect2, varscan2
- MPDZ | c.*84C>T | 3'UTR (SNP) | VAF 15/74 reads (20%) | catalogued as COSV100056032; called by muse, mutect2, varscan2
- NETO1 | c.469+23693G>T | Intron (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- OBSCN | c.5683+9G>A | Intron (SNP) | VAF 49/188 reads (26%) | called by muse, mutect2, varscan2
- OXSR1 | c.*920T>A | 3'UTR (SNP) | VAF 7/149 reads (5%) | called by muse, mutect2
- PANK3 | c.*1081C>A | 3'UTR (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- PLCH1 | c.*538C>T | 3'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- PSPC1 | c.*464T>A | 3'UTR (SNP) | VAF 13/236 reads (6%) | called by muse, mutect2
- PTGER3 | c.1077+1997T>C | Intron (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- PTPRD | c.*2964G>A | 3'UTR (SNP) | VAF 16/94 reads (17%) | catalogued as rs1393523997; called by muse, mutect2, varscan2
- PTPRT | c.*2341T>A | 3'UTR (SNP) | VAF 23/103 reads (22%) | catalogued as COSV100625883; called by muse, mutect2, varscan2
- RCSD1 | chr1:167630156 G>C | 5'Flank (SNP) | VAF 10/34 reads (29%) | called by muse, varscan2
- RSAD2 | c.*127A>G | 3'UTR (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- SELENON | c.*286G>A | 3'UTR (SNP) | VAF 45/184 reads (24%) | called by muse, mutect2, varscan2
- SLC26A7 | c.1026+52C>T | Intron (SNP) | VAF 59/209 reads (28%) | catalogued as rs1563688179; called by muse, mutect2, varscan2
- SNAI1 | c.*91C>T | 3'UTR (SNP) | VAF 13/267 reads (5%) | catalogued as COSV99723977; called by muse, mutect2
- SNCA | c.*463G>A | 3'UTR (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
- TESC | c.*185A>T | 3'UTR (SNP) | VAF 10/38 reads (26%) | catalogued as rs1030870743, COSV58810952; called by muse, mutect2, varscan2
- ZBTB44 | c.1686+288G>T | Intron (SNP) | VAF 12/270 reads (4%) | called by muse, mutect2
- ZFAND2A | chr7:1152127 G>A | 3'Flank (SNP) | VAF 39/196 reads (20%) | called by muse, mutect2, varscan2
- ZNF182 | c.*641A>C | 3'UTR (SNP) | VAF 20/47 reads (43%) | called by muse, varscan2
- ZNF385D | c.*214G>T | 3'UTR (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
